Gene-level copy-number profile of tumor specimen HCM-BROD-0416-C71-01A from HCMI case HCM-BROD-0416-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 73.1 years (26,690 days).
Specimen HCM-BROD-0416-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ad75ece5-4d1f-4cf3-872c-165c43d3e290.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0416-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,240 have no estimate.
https://portal.gdc.cancer.gov/files/b9a42136-438b-40aa-9dd8-bd9f48de70b5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 82; copy number 1: 4,003; copy number 2: 46,382; copy number 3: 7,568; copy number 4: 164; copy number 5: 64; copy number 6: 67; copy number 7: 1; copy number 25: 23; copy number 26: 2; copy number 27: 1; copy number 29: 5; copy number 31: 10; copy number 32: 4; copy number 53: 6; copy number 58: 1.

Homozygous deletions (total copy number 0; autosomes only): 82 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:5,299,864–5,856,426, 15 genes: RLN2, HMGN2P31, RLN1, AL135786.2, AL135786.1, PLGRKT, RNF152P1, CD274, AL162253.2, PDCD1LG2, AL162253.1, RIC1, AL136980.1, ERMP1, AK4P4.
- chr9:5,890,889–5,910,606, 1 gene (within-gene range 0–1): MLANA.
- chr9:19,705,338–19,894,856, 2 genes (within-gene range 0–1): C11orf98P1, AL158077.2.
- chr9:21,135,598–23,956,444, 64 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 184 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,933,699–56,603,553, 67 genes, copy number 6–58 (broad region; genes not listed).
- chr7:56,875,385–57,074,664, 7 genes, copy number 6: AC118758.1, AC069152.1, MIR4283-1, TNRC18P3, SLC29A4P1, PHKG1P4, AC122133.1.
- chr8:21,690,398–22,553,444, 27 genes, copy number 25–32 (within-gene range 2–32): GFRA2, OR6R2P, DOK2, XPO7, NPM2, FGF17, DMTN, FAM160B2, NUDT18, HR, REEP4, LGI3, SFTPC, BMP1, AC105206.1, AC105206.3, PHYHIP, MIR320A, POLR3D, AC105206.2, PIWIL2, SLC39A14, AC105910.1, RNU6-336P, PPP3CC, AC087854.1, BTF3P3.
- chr9:33,290,512–33,447,596, 5 genes, copy number 5: NFX1, Y_RNA, AQP7, AL356218.2, AQP3.
- chr9:33,503,655–34,628,086, 59 genes, copy number 5: SUGT1P1, AL139008.2, ANKRD18B, AL139008.1, SNX18P7, CYP4F26P, PRSS3P4, TRBV20OR9-2, ANXA2P2, TRBV21OR9-2, TRBV22OR9-2, TRBV23OR9-2, TRBV24OR9-2, TRBV25OR9-2, PTENP1, PTENP1-AS, TRBV26OR9-2, AL356489.2, AL356489.1, AL356489.4, LINC01251, PRSS3, UBE2R2-AS1, TRBV29OR9-2, UBE2R2, Y_RNA, RNU4ATAC11P, UBAP2, SNORD121B, SNORD121A, OSTCP8, RN7SKP114, AL354989.1, DCAF12, TUBB4BP2, AL354989.2, UBAP1, RPL35AP2, AL353662.2, RNA5SP282, AL353662.1, KIF24, RNU2-50P, SERPINH1P1, NUDT2, MYORG, C9orf24, Y_RNA, FAM219A, DNAI1, RN7SKP24, ENHO, AL160270.1, AL160270.2, CNTFR, CNTFR-AS1, RPP25L, DCTN3, ARID3C.
- chr9:38,360,427–38,424,454, 3 genes, copy number 29: AL135785.1, ALDH1B1, IGFBPL1.
- chr12:55,743,122–55,757,264, 1 gene, copy number 27 (within-gene range 3–27): GDF11.
- chr12:56,521,820–56,596,193, 2 genes, copy number 29 (within-gene range 3–29): RBMS2, RNU6-343P.
- chr12:62,260,338–62,417,431, 4 genes, copy number 31 (within-gene range 2–31): USP15, MIR6125, RNU6-595P, Metazoa_SRP.
- chr12:68,332,888–68,451,663, 1 gene, copy number 31 (within-gene range 3–31): LINC02384.
- chr12:68,746,125–68,971,570, 7 genes, copy number 7–31 (within-gene range 3–31): SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM.
- chr12:68,957,377–68,957,677, 1 gene, copy number 26: PRELID2P1.

Autosomal genes at a single copy (total copy number 1): 4,003. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
